Somatic mutation profile of cancer-model specimen HCM-SANG-0281-C18-85A (3D Organoid; aliquot HCM-SANG-0281-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0281-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0281-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22492f57-1708-4b75-911c-c83f4d818654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0281-C18-10B (Blood Derived Normal), aliquot HCM-SANG-0281-C18-10B-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05f43414-4154-44a9-8972-4d1f5c17c496

The open-access MAF lists 226 somatic variants for this specimen: 182 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 41, Nonsense Mutation 13, Frame Shift Ins 7, Frame Shift Del 2, 3'UTR 2, Splice Region 1, Splice Site 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 550/550 reads (100%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACCSL | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 213/609 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs376261378; called by muse, mutect2, varscan2
- ADAM2 | c.347del p.G116Afs*12 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as COSV55861464; called by mutect2, pindel, varscan2
- AIP | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 251/774 reads (32%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.733); catalogued as rs61741147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL136295.1 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 157/354 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1429740342; called by muse, mutect2, varscan2
- ANKRD11 | c.4064C>G p.S1355C | Missense Mutation (SNP) | VAF 296/618 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1406980325; called by muse, mutect2, varscan2
- APC | c.4053dup p.V1352Cfs*2 | Frame Shift Ins (INS) | VAF 359/505 reads (71%) | catalogued as COSV57385802; called by mutect2, pindel, varscan2
- ASMT | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 214/563 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs767931039, COSV67109635; called by muse, mutect2, varscan2
- CACTIN | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 163/788 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs752325115, COSV50272181; called by muse, mutect2, varscan2
- CDC42BPB | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 122/270 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs751814078; called by muse, mutect2, varscan2
- CDH24 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 141/272 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs757584877, COSV57460879; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1581G>C p.K527N | Missense Mutation (SNP) | VAF 157/349 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs760045973; called by muse, mutect2, varscan2
- CHI3L1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 281/480 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs1280587751; called by muse, mutect2
- CHRNB3 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 92/529 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755411549; called by muse, mutect2, varscan2
- COL6A1 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 332/632 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1034465336, COSV62613369; called by muse, mutect2, varscan2
- COL6A2 | c.2218G>A p.D740N | Missense Mutation (SNP) | VAF 231/521 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as rs1474632772, COSV56001822; called by muse, mutect2, varscan2
- COPZ2 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 126/411 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs866362844, COSV50057619; called by muse, mutect2, varscan2
- CXCR1 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 178/533 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs552902470, COSV55281877; called by muse, mutect2, varscan2
- DCAF12L1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 253/1034 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV64421788; called by muse, mutect2, varscan2
- DGKB | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 289/562 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770185578, COSV51828108; called by muse, mutect2, varscan2
- DGKK | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 156/523 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101053180; called by muse, mutect2, varscan2
- DMBT1 | c.6025G>A p.D2009N (on ENST00000338354 / NM_001377530.1; = p.D1252N on NM_004406.3) | Missense Mutation (SNP) | VAF 108/216 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.245); catalogued as rs756440328, COSV57558074; called by muse, mutect2, varscan2
- EFEMP1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 17/503 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV62615830; called by muse, mutect2
- EML5 | c.1541A>T p.K514M | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100715735; called by muse, mutect2, varscan2
- FIGN | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 204/656 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as rs1270474716, COSV60771418; called by muse, mutect2, varscan2
- FPR2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 166/567 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs778561198, COSV60673907; called by muse, mutect2, varscan2
- FRMPD1 | c.4421G>A p.R1474Q | Missense Mutation (SNP) | VAF 250/775 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100899545; called by muse, mutect2, varscan2
- GALNT13 | c.543G>C p.R181S | Missense Mutation (SNP) | VAF 133/375 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67209831; called by muse, mutect2, varscan2
- GBX2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 336/996 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs753718265; called by muse, varscan2
- GOLGA8Q | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 135/309 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1244227446; called by muse, mutect2, varscan2
- GRIP1 | c.2387C>T p.P796L (on ENST00000359742 / NM_001379345.1; = p.P744L on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 205/398 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs751518904; called by muse, mutect2, varscan2
- IMPDH1 | c.1328C>T p.S443L (on ENST00000470772 / NM_001142573.2; = p.S529L on NM_000883.4) | Missense Mutation (SNP) | VAF 223/712 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs143391643, COSV58318376; called by muse, mutect2, varscan2
- INHBC | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 258/507 reads (51%) | catalogued as rs1454095163; called by muse, mutect2, varscan2
- KCNA4 | c.15G>T p.M5I | Missense Mutation (SNP) | VAF 151/458 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV60253974; called by muse, mutect2, varscan2
- KIF21B | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 164/556 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs771556735, COSV59757181; called by muse, mutect2, varscan2
- LAMA1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150637419; called by muse, mutect2, varscan2
- LRRC30 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 20/576 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV67301708; called by muse, mutect2
- LUC7L3 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53586886, COSV53589948; called by muse, mutect2, varscan2
- MAP10 | c.839C>A p.S280* | Nonsense Mutation (SNP) | VAF 325/952 reads (34%) | catalogued as COSV69362955; called by muse, mutect2, varscan2
- MAP3K4 | c.4225G>T p.E1409* | Nonsense Mutation (SNP) | VAF 95/554 reads (17%) | catalogued as COSV100815590, COSV62334810, COSV62335894; called by muse, mutect2, varscan2
- MSH2 | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 170/605 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99254727; called by muse, mutect2, varscan2
- MYRFL | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 127/287 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs1030864191; called by muse, mutect2, varscan2
- NCOA3 | c.3052G>T p.E1018* | Nonsense Mutation (SNP) | VAF 88/677 reads (13%) | catalogued as COSV59070342; called by muse, mutect2, varscan2
- NFATC2IP | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 175/487 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs748324737; called by muse, mutect2, varscan2
- NLRP3 | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 387/583 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs199856287, CM1413286, COSV60219661, COSV60221397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOVA2 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 304/966 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs754714738, COSV54358585; called by muse, mutect2, varscan2
- NPIPB11 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 30/544 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.938); catalogued as rs200886614; called by muse, mutect2
- NUTM2A | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 94/516 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs771614296; called by muse, mutect2, varscan2
- OR52B4 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 182/775 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs267602877, COSV68768715; called by muse, mutect2, varscan2
- PCDH11X | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 181/668 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs1161362870, COSV100011655; called by muse, mutect2, varscan2
- PCDHB8 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 108/553 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as rs1372149225, COSV50760033; called by muse, mutect2, varscan2
- PNN | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 234/504 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as COSV99397384; called by muse, mutect2, varscan2
- RAD51AP2 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 181/580 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs989120561; called by muse, mutect2, varscan2
- RASGRP3 | c.1535C>T p.A512V (on ENST00000402538 / NM_001349975.2; = p.A511V on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs199562103, COSV67821827; called by muse, mutect2, varscan2
- RIMS1 | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 107/357 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1233472578; called by muse, mutect2, varscan2
- RPGR | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 170/531 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs768274240; called by muse, mutect2, varscan2
- RUFY4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 217/703 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs768944600; called by muse, mutect2, varscan2
- SDK1 | c.5663C>A p.P1888H | Missense Mutation (SNP) | VAF 233/862 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369769759; called by muse, mutect2, varscan2
- SEMA3E | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.471); catalogued as COSV57078853; called by muse, mutect2, varscan2
- SERPINA4 | c.1000C>G p.P334A | Missense Mutation (SNP) | VAF 231/449 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs1182258902; called by muse, mutect2, varscan2
- SNAP25 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 186/946 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV54774956; called by muse, mutect2, varscan2
- SPATA31D1 | c.171T>A p.N57K | Missense Mutation (SNP) | VAF 115/254 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs764489996; called by muse, mutect2, varscan2
- SPRTN | c.718+8C>T | Splice Region (SNP) | VAF 40/180 reads (22%) | catalogued as rs368787875; called by muse, mutect2, varscan2
- STK26 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV61229803; called by muse, mutect2, varscan2
- TCOF1 | c.1564G>A p.G522S (on ENST00000377797 / NM_001135243.1; = p.G445S on NM_000356.4) | Missense Mutation (SNP) | VAF 574/574 reads (100%) | SIFT tolerated (0.85); PolyPhen benign (0.07); catalogued as rs377510593, COSV60347631; called by muse, mutect2, varscan2
- TEX13C | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 20/794 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.337); catalogued as rs1394127432; called by muse, mutect2
- TLCD1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 353/588 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.417); catalogued as rs199910670; called by muse, mutect2, varscan2
- TMEM165 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 362/765 reads (47%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.094); catalogued as rs966622982; called by muse, mutect2, varscan2
- TNIP3 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 41/106 reads (39%) | catalogued as COSV50247957; called by muse, mutect2, varscan2
- TTN | c.22357G>A p.G7453R (on ENST00000591111; = p.G6526R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 248/427 reads (58%) | PolyPhen probably damaging (0.987); catalogued as rs374739582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5C | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 105/219 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71658944; called by muse, mutect2, varscan2
- WDR41 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 131/290 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.441); catalogued as COSV56998839; called by muse, mutect2, varscan2
- WDR62 | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 318/992 reads (32%) | catalogued as COSV54332987; called by muse, mutect2, varscan2
- XIRP2 | c.9407_9408del p.R3136Ifs*2 (on ENST00000628543; = p.R3311Ifs*2 on NM_152381.6) | Frame Shift Del (DEL) | VAF 118/492 reads (24%) | catalogued as rs1559045742; called by pindel, varscan2
- ZNF35 | c.232G>C p.A78P | Missense Mutation (SNP) | VAF 196/416 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56077080; called by muse, mutect2, varscan2
- ZNF486 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs782722317; called by muse, mutect2, varscan2
- ZNF768 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 208/763 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs780017304; called by muse, mutect2, varscan2
- ZNF80 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 229/467 reads (49%) | catalogued as COSV57362231; called by muse, mutect2, varscan2
- AARS2 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 218/605 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- ABCA13 | c.14350A>G p.M4784V | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AC008687.4 | c.1005A>C p.*335Cext*26 | Nonstop Mutation (SNP) | VAF 178/542 reads (33%) | called by muse, mutect2, varscan2
- ACVR1 | c.818G>C p.R273T | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADIPOR2 | c.905T>A p.F302Y | Missense Mutation (SNP) | VAF 220/486 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, mutect2
- AFDN | c.1262T>C p.L421P | Missense Mutation (SNP) | VAF 84/385 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANO1 | c.2712G>T p.M904I | Missense Mutation (SNP) | VAF 135/400 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- APOB | c.7465dup p.I2489Nfs*56 | Frame Shift Ins (INS) | VAF 117/573 reads (20%) | called by mutect2, pindel, varscan2
- ARMCX5 | c.1499A>T p.N500I | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2C1 | c.1616T>A p.L539H | Missense Mutation (SNP) | VAF 137/296 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ATP8A2 | c.1724G>C p.R575T | Missense Mutation (SNP) | VAF 231/386 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BEGAIN | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 274/600 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, varscan2
- C9orf43 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CACNA1H | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 357/903 reads (40%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC146 | c.1414A>C p.K472Q | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CCT6B | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CDAN1 | c.2242G>T p.V748F | Missense Mutation (SNP) | VAF 203/457 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CDC23 | c.1439_1440insTCATTTGTAGGCTTCATGAACAGTT p.L480Ffs*4 | Nonsense Mutation (INS) | VAF 62/144 reads (43%) | called by mutect2, varscan2
- CENPC | c.780A>C p.K260N | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHD4 | c.3340C>T p.R1114* (on ENST00000357008 / NM_001363606.2; = p.R1127* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 134/323 reads (41%) | called by muse, mutect2, varscan2
- CHI3L1 | c.326T>A p.I109K | Missense Mutation (SNP) | VAF 273/466 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CSMD3 | c.10247C>G p.T3416S (on ENST00000297405 / NM_001363185.1; = p.T3247S on NM_052900.3) | Missense Mutation (SNP) | VAF 87/453 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CWC25 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 222/723 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CYP2D7 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 180/372 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.046); called by muse, mutect2
- DNAH10 | c.6246A>T p.R2082S (on ENST00000409039; = p.R2021S on NM_207437.3) | Missense Mutation (SNP) | VAF 256/483 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAT2 | c.4519G>T p.V1507L | Missense Mutation (SNP) | VAF 215/462 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- FREM2 | c.6986G>T p.G2329V | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- GOLGA6L7 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 124/317 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GPR22 | c.1214G>A p.W405* | Nonsense Mutation (SNP) | VAF 47/176 reads (27%) | called by muse, mutect2, varscan2
- GRIN2A | c.2709C>A p.N903K | Missense Mutation (SNP) | VAF 143/330 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- HELZ | c.5677G>T p.A1893S | Missense Mutation (SNP) | VAF 223/701 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- HPSE2 | c.649T>G p.S217A | Missense Mutation (SNP) | VAF 135/276 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSPG2 | c.5732C>T p.A1911V | Missense Mutation (SNP) | VAF 273/542 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IBTK | c.3426T>A p.H1142Q | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IL18R1 | c.404_405insG p.F135Lfs*7 | Frame Shift Ins (INS) | VAF 57/190 reads (30%) | called by mutect2, pindel, varscan2
- INSL3 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 860/1369 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.086); called by muse, mutect2
- KAT7 | c.386dup p.T130Nfs*8 | Frame Shift Ins (INS) | VAF 133/561 reads (24%) | called by mutect2, pindel, varscan2
- KCNQ2 | c.777C>G p.D259E | Missense Mutation (SNP) | VAF 277/2005 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNS2 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 164/735 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KDM4B | c.1318G>C p.D440H | Missense Mutation (SNP) | VAF 196/608 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- KDM4D | c.374A>T p.Y125F | Missense Mutation (SNP) | VAF 158/511 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1958 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 185/375 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF4B | c.2239C>A p.L747I | Missense Mutation (SNP) | VAF 499/499 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.222); called by muse, varscan2
- KNTC1 | c.4156G>T p.A1386S | Missense Mutation (SNP) | VAF 108/239 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KTN1 | c.2256A>T p.E752D | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRTM1 | c.1149T>A p.D383E | Missense Mutation (SNP) | VAF 353/1015 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTV1 | c.1075A>G p.N359D | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LZIC | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 116/272 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- METTL23 | c.323A>G p.D108G | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MGAM2 | c.6884C>A p.T2295N | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2, varscan2
- MRO | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 130/268 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, varscan2
- MRO | c.386T>A p.F129Y | Missense Mutation (SNP) | VAF 130/268 reads (49%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.447); called by muse, varscan2
- MRO | c.385T>A p.F129I | Missense Mutation (SNP) | VAF 132/278 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.113); called by muse, varscan2
- MTMR1 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 185/571 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOP14 | c.104A>C p.K35T | Missense Mutation (SNP) | VAF 344/728 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NRXN3 | c.1232A>C p.K411T (on ENST00000335750 / NM_001330195.2; = p.K38T on NM_004796.6) | Missense Mutation (SNP) | VAF 119/256 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OPA1 | c.2389G>A p.D797N (on ENST00000361510 / NM_130837.3; = p.D742N on NM_015560.3) | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- OPRK1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 371/1443 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51B4 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 82/560 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PCDH15 | c.4655A>C p.E1552A (on ENST00000644397 / NM_001354429.2; = p.E1501A on NM_001142769.3) | Missense Mutation (SNP) | VAF 125/244 reads (51%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PET100 | c.85T>G p.W29G | Missense Mutation (SNP) | VAF 310/522 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by mutect2, varscan2
- PGBD1 | c.1072_1073insA p.S358Yfs*5 | Frame Shift Ins (INS) | VAF 163/308 reads (53%) | called by mutect2, pindel*, varscan2
- PRKG1 | c.100C>G p.Q34E | Missense Mutation (SNP) | VAF 227/454 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF4B | c.1540G>C p.V514L | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRR33 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 348/1364 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by mutect2, varscan2
- PZP | c.2844A>T p.E948D | Missense Mutation (SNP) | VAF 186/360 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB28 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- RICTOR | c.3097C>T p.H1033Y | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ROBO2 | c.1031C>A p.A344D | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RPE | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 146/510 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- SBSPON | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 83/415 reads (20%) | called by muse, mutect2, varscan2
- SHANK1 | c.3961G>A p.G1321R | Missense Mutation (SNP) | VAF 341/1068 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC16A4 | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 287/423 reads (68%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC39A3 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 245/920 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- SLC4A5 | c.2060-16_2069del p.X687_splice | Splice Site (DEL) | VAF 36/208 reads (17%) | called by mutect2, pindel, varscan2
- SLC5A7 | c.1376T>A p.L459* | Nonsense Mutation (SNP) | VAF 177/523 reads (34%) | called by muse, mutect2, varscan2
- SOGA1 | c.3593G>A p.G1198D | Missense Mutation (SNP) | VAF 277/1482 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPATA3 | c.739C>A p.R247S | Missense Mutation (SNP) | VAF 265/918 reads (29%) | SIFT tolerated, low confidence (0.66); called by muse, mutect2, varscan2
- SSU72P8 | c.246A>C p.L82F | Missense Mutation (SNP) | VAF 99/382 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYCP2 | c.2797_2798insT p.N933Ifs*4 | Frame Shift Ins (INS) | VAF 34/334 reads (10%) | called by mutect2, pindel, varscan2
- TBR1 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 587/882 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TCF7L2 | c.759_760insTTTT p.P254Ffs*75 (on ENST00000355995 / NM_001367943.1; = p.P231Ffs*75 on NM_030756.5) | Frame Shift Ins (INS) | VAF 156/394 reads (40%) | called by mutect2, pindel, varscan2
- TENM4 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 44/1220 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2
- TLE4 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 151/300 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TOPAZ1 | c.1579A>T p.R527W | Missense Mutation (SNP) | VAF 144/298 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- TPM3 | c.515T>A p.I172N | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, varscan2
- TPR | c.5574G>T p.K1858N | Missense Mutation (SNP) | VAF 99/356 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRIM69 | c.578A>G p.K193R (on ENST00000329464 / NM_182985.5; = p.K34R on NM_080745.5) | Missense Mutation (SNP) | VAF 151/314 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- TRPC1 | c.1616A>C p.K539T (on ENST00000476941 / NM_001251845.2; = p.K505T on NM_003304.4) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TSR1 | c.1283A>G p.D428G | Missense Mutation (SNP) | VAF 116/415 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTC24 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 252/884 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- UFL1 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP39 | c.1351A>C p.I451L | Missense Mutation (SNP) | VAF 98/306 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- VGF | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 464/1431 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- WDR75 | c.1546A>T p.S516C | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- WWC2 | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 77/128 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- YARS1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 152/360 reads (42%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZKSCAN8 | c.652A>T p.T218S | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZNF185 | c.1961A>G p.Y654C | Missense Mutation (SNP) | VAF 134/457 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF304 | c.982G>T p.V328F | Missense Mutation (SNP) | VAF 241/670 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ZNF419 | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 174/658 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.011); called by mutect2, varscan2
- ZNF449 | c.1082T>G p.L361R | Missense Mutation (SNP) | VAF 222/709 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ZNF813 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ZSCAN25 | c.700G>C p.D234H | Missense Mutation (SNP) | VAF 154/467 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ABCA9 | c.4359C>T p.P1453= | Silent (SNP) | VAF 177/655 reads (27%) | catalogued as rs371992345; called by muse, mutect2, varscan2
- AJM1 | c.1368G>C p.G456= | Silent (SNP) | VAF 868/1392 reads (62%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.756G>T p.G252= (on ENST00000236925 / NM_001297707.2; = p.G241= on NM_203459.3) | Silent (SNP) | VAF 20/661 reads (3%) | catalogued as COSV52674580; called by muse, mutect2
- CAP2 | c.789A>G p.L263= | Silent (SNP) | VAF 161/333 reads (48%) | called by muse, mutect2, varscan2
- CNTN5 | c.528C>A p.T176= | Silent (SNP) | VAF 96/267 reads (36%) | catalogued as rs201262648; called by muse, mutect2, varscan2
- COL22A1 | c.2007C>G p.G669= | Silent (SNP) | VAF 173/800 reads (22%) | catalogued as COSV57351489; called by muse, mutect2, varscan2
- CROCC | c.2520C>A p.S840= | Silent (SNP) | VAF 166/523 reads (32%) | called by muse, mutect2, varscan2
- CYFIP1 | c.2700C>T p.S900= | Silent (SNP) | VAF 129/262 reads (49%) | called by muse, mutect2, varscan2
- DHRS2 | c.33C>T p.G11= | Silent (SNP) | VAF 150/356 reads (42%) | called by muse, mutect2, varscan2
- DNER | c.1326C>T p.N442= | Silent (SNP) | VAF 145/549 reads (26%) | catalogued as rs201881122, COSV59161793; called by muse, varscan2
- ECSIT | c.492C>A p.V164= | Silent (SNP) | VAF 145/438 reads (33%) | catalogued as rs567885463; called by muse, mutect2, varscan2
- EPHA5 | c.801G>T p.V267= | Silent (SNP) | VAF 146/335 reads (44%) | catalogued as COSV56632343; called by muse, mutect2, varscan2
- ERGIC3 | c.156G>T p.T52= | Silent (SNP) | VAF 177/1180 reads (15%) | catalogued as rs757574043; called by muse, mutect2, varscan2
- FBLN1 | c.1449C>T p.D483= | Silent (SNP) | VAF 179/393 reads (46%) | catalogued as rs553677396; called by muse, mutect2, varscan2
- GOLGA6D | c.1573C>T p.L525= | Silent (SNP) | VAF 138/1083 reads (13%) | catalogued as rs1156429355; called by muse, varscan2
- GTF3C6 | c.447C>T p.D149= | Silent (SNP) | VAF 124/355 reads (35%) | catalogued as rs759091734, COSV100328790; called by muse, mutect2, varscan2
- HDAC11 | c.834C>T p.I278= | Silent (SNP) | VAF 171/353 reads (48%) | catalogued as rs200123307; called by muse, mutect2, varscan2
- HPX | c.1203G>A p.E401= | Silent (SNP) | VAF 251/1159 reads (22%) | catalogued as rs1344755587; called by muse, mutect2, varscan2
- ING5 | c.18C>T p.Y6= | Silent (SNP) | VAF 252/756 reads (33%) | called by muse, mutect2, varscan2
- KHNYN | c.1752C>T p.G584= | Silent (SNP) | VAF 209/442 reads (47%) | called by muse, mutect2, varscan2
- KLHL17 | c.726C>T p.V242= | Silent (SNP) | VAF 145/290 reads (50%) | catalogued as rs369440263; called by muse, mutect2, varscan2
- LAMA5 | c.5712C>T p.D1904= | Silent (SNP) | VAF 331/2355 reads (14%) | catalogued as rs139559822; called by muse, mutect2, varscan2
- MAP3K4 | c.4224G>T p.V1408= | Silent (SNP) | VAF 97/558 reads (17%) | called by muse, mutect2, varscan2
- NT5C1B | c.822C>T p.D274= (on ENST00000359846 / NM_001199086.2; = p.D214= on NM_033253.4) | Silent (SNP) | VAF 247/710 reads (35%) | catalogued as rs191446499; called by muse, varscan2
- NTN1 | c.327C>A p.T109= | Silent (SNP) | VAF 316/1098 reads (29%) | called by muse, mutect2, varscan2
- OR52E2 | c.375T>C p.Y125= | Silent (SNP) | VAF 192/835 reads (23%) | catalogued as rs769633161; called by muse, mutect2, varscan2
- PAPOLA | c.813A>G p.K271= | Silent (SNP) | VAF 82/174 reads (47%) | called by muse, mutect2, varscan2
- PRPS2 | c.102G>A p.K34= | Silent (SNP) | VAF 191/581 reads (33%) | called by muse, mutect2, varscan2
- RGS20 | c.456G>A p.P152= | Silent (SNP) | VAF 300/1282 reads (23%) | catalogued as rs776294392, COSV52017481; called by muse, mutect2, varscan2
- RNPEP | c.87C>T p.S29= | Silent (SNP) | VAF 302/950 reads (32%) | called by muse, varscan2
- SEMA6A | c.1443A>G p.G481= | Silent (SNP) | VAF 150/283 reads (53%) | called by muse, mutect2, varscan2
- SEMG1 | c.633A>G p.K211= | Silent (SNP) | VAF 97/610 reads (16%) | called by muse, mutect2, varscan2
- SLC15A5 | c.522T>C p.C174= | Silent (SNP) | VAF 196/392 reads (50%) | called by muse, mutect2, varscan2
- SLC34A3 | c.531G>A p.A177= | Silent (SNP) | VAF 479/484 reads (99%) | catalogued as rs781706240; called by muse, mutect2, varscan2
- SOAT1 | c.837A>G p.L279= | Silent (SNP) | VAF 166/469 reads (35%) | called by muse, mutect2, varscan2
- SOBP | c.1536G>A p.P512= | Silent (SNP) | VAF 315/924 reads (34%) | catalogued as rs781110018; called by muse, mutect2, varscan2
- SYNE1 | c.5721G>A p.K1907= (on ENST00000367255 / NM_182961.4; = p.K1914= on NM_033071.3) | Silent (SNP) | VAF 158/715 reads (22%) | catalogued as COSV54987592; called by muse, mutect2, varscan2
- TEX13D | c.1461C>A p.A487= | Silent (SNP) | VAF 113/398 reads (28%) | called by muse, mutect2, varscan2
- TGIF2LX | c.24G>A p.P8= | Silent (SNP) | VAF 191/592 reads (32%) | catalogued as rs1216899464, COSV52213098, COSV52213469; called by muse, mutect2, varscan2
- WASHC5 | c.840G>T p.V280= | Silent (SNP) | VAF 166/346 reads (48%) | called by muse, mutect2, varscan2
- ZFHX4 | c.5952A>G p.Q1984= | Silent (SNP) | VAF 428/871 reads (49%) | catalogued as rs1337147116; called by muse, mutect2, varscan2
- AC092070.2 | n.952G>A | RNA (SNP) | VAF 149/456 reads (33%) | called by muse, mutect2, varscan2
- ATP11B | c.*308T>A | 3'UTR (SNP) | VAF 60/130 reads (46%) | called by muse, mutect2, varscan2
- COL6A5 | c.*618C>T | 3'UTR (SNP) | VAF 105/214 reads (49%) | called by muse, mutect2, varscan2
